Somatic mutation profile of tumor specimen TCGA-09-2045-01A (aliquot TCGA-09-2045-01A-01W-0799-08) from TCGA case TCGA-09-2045, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 50.1 years (18,285 days).
Specimen TCGA-09-2045-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6f02c3f-0d5c-4ee0-a660-ad798f98736b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2045-11A (Solid Tissue Normal), aliquot TCGA-09-2045-11A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cff58e3-4d36-492c-8958-47536ef6e8d1

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 101/132 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3590C>G p.T1197R | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55285639; called by muse, mutect2, varscan2
- ABCC10 | c.1586G>A p.G529E (on ENST00000372530 / NM_001198934.2; = p.G486E on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759259706, COSV55084332; called by muse, mutect2, varscan2
- ACVR2B | c.92A>T p.Y31F | Missense Mutation (SNP) | VAF 111/128 reads (87%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV61701112; called by muse, mutect2, varscan2
- ANAPC4 | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV59542927; called by muse, mutect2, varscan2
- ATIC | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52691815; called by muse, mutect2, varscan2
- CCT5 | c.1407T>G p.N469K | Missense Mutation (SNP) | VAF 113/355 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV54723149; called by muse, mutect2, varscan2
- CD163 | c.3169C>G p.L1057V | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV63129413, COSV63130556; called by muse, mutect2, varscan2
- CDH2 | c.1942A>G p.I648V | Missense Mutation (SNP) | VAF 96/188 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52271679; called by muse, varscan2
- CIP2A | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV55417103; called by muse, mutect2, varscan2
- CNOT1 | c.2639C>A p.T880N | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV55312933; called by muse, mutect2, varscan2
- CUL9 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs375566962, COSV52728896; called by muse, mutect2, varscan2
- FSHR | c.1046A>T p.K349M | Missense Mutation (SNP) | VAF 580/1136 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV58617482, COSV58624672; called by muse, mutect2, varscan2
- KCNJ12 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100054023, COSV59167049; called by muse, mutect2, varscan2
- KRT72 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53373180; called by muse, mutect2, varscan2
- LAMP3 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 169/476 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55613481; called by muse, mutect2, varscan2
- LRIT3 | c.866G>T p.R289I | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100015857; called by muse, mutect2
- LRRIQ1 | c.3582del p.E1195Kfs*10 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as COSV67825907; called by mutect2, pindel, varscan2
- MOV10 | c.110C>G p.T37S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54144203; called by muse, mutect2, varscan2
- MYOF | c.3169A>G p.I1057V | Missense Mutation (SNP) | VAF 75/96 reads (78%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as rs748524728, COSV63700220; called by muse, mutect2, varscan2
- PCDH15 | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 226/510 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57263259, COSV57334250; called by muse, varscan2
- PGK1 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 133/388 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs948792612, COSV100540557; called by muse, mutect2, varscan2
- RETSAT | c.486T>A p.N162K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as COSV55524692; called by muse, mutect2, varscan2
- SHC4 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 264/595 reads (44%) | catalogued as COSV60109410; called by muse, mutect2, varscan2
- SMCHD1 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99860592; called by muse, mutect2, varscan2
- SMCO1 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV58836711; called by muse, mutect2, varscan2
- STXBP5L | c.1767T>A p.S589R | Missense Mutation (SNP) | VAF 111/269 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.153); catalogued as COSV56500041; called by muse, mutect2, varscan2
- TCF20 | c.3640C>T p.P1214S | Missense Mutation (SNP) | VAF 185/218 reads (85%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.048); catalogued as COSV59488338; called by muse, mutect2, varscan2
- TRUB2 | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV65759131; called by muse, mutect2, varscan2
- UBA2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99875327; called by muse, varscan2
- UGDH | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); catalogued as COSV57096616; called by muse, mutect2, varscan2
- ZNF521 | c.2248A>G p.K750E | Missense Mutation (SNP) | VAF 100/217 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64122246; called by muse, mutect2, varscan2
- ZNF746 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV61406296; called by muse, mutect2, varscan2
- BAHCC1 | c.7766C>G p.S2589C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJA2 | c.1046_1047+36del p.X349_splice | Splice Site (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel
- ACTN1 | c.693C>T p.A231= | Silent (SNP) | VAF 102/213 reads (48%) | catalogued as COSV99517261; called by muse, mutect2, varscan2
- CASP14 | c.198A>G p.E66= | Silent (SNP) | VAF 21/358 reads (6%) | catalogued as COSV55665949; called by muse, mutect2
- CHGB | c.1341T>G p.R447= | Silent (SNP) | VAF 18/337 reads (5%) | catalogued as COSV100972909; called by muse, mutect2
- DLC1 | c.1560G>A p.R520= (on ENST00000276297 / NM_001348081.2; = p.R83= on NM_006094.5) | Silent (SNP) | VAF 65/143 reads (45%) | catalogued as COSV52290250; called by muse, mutect2, varscan2
- DMRT1 | c.771T>A p.L257= | Silent (SNP) | VAF 48/193 reads (25%) | catalogued as COSV66518963; called by muse, mutect2, varscan2
- EPHA5 | c.2445A>G p.K815= | Silent (SNP) | VAF 109/249 reads (44%) | catalogued as COSV56631096; called by muse, mutect2, varscan2
- INTS10 | c.114A>G p.A38= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs375410459; called by muse, mutect2
- PPP2R2C | c.501C>A p.I167= | Silent (SNP) | VAF 107/236 reads (45%) | catalogued as COSV58670026, COSV58670277; called by muse, mutect2, varscan2
- TLN2 | c.6936G>A p.G2312= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as COSV60885550; called by muse, mutect2, varscan2
